Surgical pathology report (de-identified scan), TCGA case TCGA-76-6664, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6664-01A (Primary Tumor).

[page 1 of 3]
ADDED

CGA-76-6664

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. SPECIMEN DESIGNATED "Right frontal glioma": GLIOBLASTOMA, WHO
GRADE iv.

This diagnostic report has been personally interpreted by the signatory
of record.

Aperio

Ki67

Percent : 48%

Cells counted : 60,041 cells

This test was performed by IHC in conjunction with the Aperio-computer
assisted image analysis.

Addendum

IMMUNOHISTOCHEMICAL STAIN

GFAP: POSITIVE STAINING OF TUMOR CELLS.

[page 2 of 3]
Microscopic Description:

1. Right frontal glioma:

History of Previous Tumor/Familial Syndrome: None known

Specimen Type/Procedure: Resection

Specimen Handling: Squash / smear / touch preparation

Frozen section

Unfrozen for routine permanent

paraffin sections

Specimen Size: Greatest dimension: 2.0 cm

Additional dimension: 2.0 cm

Additional dimension: 0.4 cm

Laterality: Right

Tumor Site: Brain/cerebrum-Frontal

Histologic Type and Grade: Glioblastoma (WHO grade IV)

Histologic Grade: WHO Grade IV

Margins: Cannot be assessed

Ancillary Studies: Immunohistochemistry: Ki67 and GFAP

The tumor is composed of pleomorphic glial cells. Mitotic figures are identified in tumor cells. Foci of necrosis including pseudopalisading necrosis are identified. The areas of necrosis are best seen on the deeper levels of slide 1B. Small areas of endothelial proliferation are also identified.

An addendum with the results of immunohistochemical stains will be issued.

This case was reviewed in conference with [REDACTED]

Frozen Section Diagnosis:

1. Specimen designated "Right frontal glioma": Malignant glioma with features of glioblastoma. Frozen section diagnosis by [REDACTED]

Clinical History and Diagnosis:

brain tumor

Source of Specimen:

1: Right frontal glioma

Gross Description:

1. Right frontal glioma: Received fresh for frozen section analysis and a specimen container labeled with the patient's name and "#1 right [REDACTED]

[page 3 of 3]
frontal malignant glioma consistent with glioma" are multiple fragments of tan-pink soft tissue measuring 2.0 x 2.0 x 0.4 cm in aggregate. Touch preps are prepared. Approximately 50% the specimen is submitted for frozen section analysis. The specimen is entirely submitted in 2 cassettes as follows:

- A frozen section control
- D. remainder of the specimen

Histology Laboratory

H&E

Part 1: Right frontal glioma

DEEPER

DEEPER

DEEPER

GLIAL FIBRILLARY ACIDIC PROTEIN (GFAP)

KI 67 (Aperio)

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. Applied Immunohistochemistry,

2. Pathway Her-2/neu (4B5) (Rabbit monoclonal) - Formalin-fixed, paraffin embedded tissue. UltraView Universal Detection Kit.

Interpretation follows the manufacturer's recommendation.

3. EGFR (3C6) (Mouse Monoclonal) Formalin-fixed, paraffin embedded tissue. UltraView Universal Detection Kit.

4. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristics determined by the Clinical Laboratory of

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 498ad062-89f1-43a8-b9b1-7b19bb2b84ea (TCGA-76-6664.140F178D-A96F-4F36-BACE-1199EBB43964.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).